TARGET case TARGET-30-PAPTFZ — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ac0fc19e-159d-5fff-960e-a54101be7a44

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 1 years; Vital status: Dead; Days to death: 779 days (2.1 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Classification of tumor: primary; Age at diagnosis: 1.5 years (564 days); Year of diagnosis: 2006; Days to last follow up: 779 days (2.1 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: High.
   Pathology details: Necrosis percent: 0; Percent tumor nuclei: 5.
   Treatment given: Protocol identifier: ANBL0421.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: ANBL0621.

Follow-up (2 entries)
- Days to follow up: 516 days (1.4 years); Progression or recurrence anatomic site: Bone, NOS; Days to first event: 516 days (1.4 years); First event: Relapse.
- Days to follow up: 779 days (2.1 years); Year of follow up: 2008.

Molecular and laboratory tests
- MYCN amplification: Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAPTFZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAPTFZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 779
- Protocol: ANBL00B1, ANBL0421, ANBL0621
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.16
- Histology: Unfavorable
- ICDO Description: Adrenal gland, NOS Suprarenal gland Adrenal, NOS
- Percent Tumor: 5
- Percent Necrosis: 0
- Percent Tumor v/s Stroma: 5/95
- Site of Relapse: Bone
